Somatic mutation profile of tumor specimen C3N-02587-01 (aliquot CPT0148080010) from CPTAC case C3N-02587, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 59.7 years (21,789 days).
Specimen C3N-02587-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e0f3d68-ec05-4942-94f0-ce95b05b34d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02587-71 (Blood Derived Normal), aliquot CPT0148110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51312496-a381-44d8-9f0a-b6f8200337da

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 101/436 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs13306085; called by muse, mutect2, varscan2
- AJAP1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); catalogued as rs867387769; called by muse, mutect2, varscan2
- HERC6 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1408664628; called by muse, mutect2
- MPV17 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 89/579 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV51991374; called by muse, mutect2, varscan2
- MRGPRX2 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.104); catalogued as rs200815634, COSV61674398; called by muse, mutect2
- MYO5B | c.4921C>A p.R1641S | Missense Mutation (SNP) | VAF 106/410 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV104373969; called by muse, mutect2, varscan2
- NPAP1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs749766364, COSV100275741; called by muse, mutect2, varscan2
- PKD1L3 | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs188963934, COSV100626285; called by muse, mutect2, varscan2
- VHL | c.5C>G p.P2R | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as rs111246617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP12 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 35/142 reads (25%) | called by muse, mutect2, varscan2
- AKNA | c.2669T>C p.L890P | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ANKRD10 | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 9/300 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2
- AP4E1 | c.695T>A p.M232K | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- EML6 | c.3943A>T p.I1315F | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ETS1 | c.466T>G p.S156A | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- SRSF1 | c.239dup p.D80Efs*41 | Frame Shift Ins (INS) | VAF 30/149 reads (20%) | called by mutect2, pindel, varscan2
- STAT2 | c.1705A>T p.K569* | Nonsense Mutation (SNP) | VAF 89/312 reads (29%) | called by muse, mutect2, varscan2
- TMC4 | c.2110G>A p.A704T (on ENST00000617472 / NM_001145303.3; = p.A698T on NM_144686.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by mutect2, varscan2
- ZNF729 | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- BTBD2 | c.1536C>T p.S512= | Silent (SNP) | VAF 41/230 reads (18%) | catalogued as rs529159931; called by muse, mutect2, varscan2
- CACNG6 | c.327C>T p.P109= | Silent (SNP) | VAF 51/198 reads (26%) | called by muse, mutect2, varscan2
- COL5A3 | c.4281C>T p.G1427= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs768598683, COSV53406053, COSV53415977; called by muse, mutect2, varscan2
- CTC1 | c.3426C>T p.L1142= | Silent (SNP) | VAF 67/287 reads (23%) | catalogued as rs745512137, CX121915; called by muse, mutect2, varscan2
- NSUN3 | c.345C>A p.L115= | Silent (SNP) | VAF 46/311 reads (15%) | called by muse, mutect2, varscan2
- TRPM5 | c.699T>C p.D233= | Silent (SNP) | VAF 75/210 reads (36%) | catalogued as rs751774807; called by muse, mutect2, varscan2
- AC245748.1 | c.16-26574C>T | Intron (SNP) | VAF 54/236 reads (23%) | catalogued as rs1465651344; called by muse, mutect2, varscan2
- ZMYND8 | c.26-8790A>G | Intron (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
